CCDI case PBCIWV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/2dd51430-d262-4cfa-b8cf-629dddf86984

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 12.1 years (4,408 days).

Biospecimens (3 samples)
- Sample 0DSW9E: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSW9L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSWA2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
